CPTAC case C3N-01369 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e59a7d58-adf4-4d05-8a7f-c3013285b568

Demographics
Sex at birth: female; Race: white; Year of birth: 1959; Vital status: Dead; Days to death: 606 days (1.7 years); Year of death: 2018; Country of birth: Poland.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Temporal lobe; Age at diagnosis: 57.5 years (21,015 days); Year of diagnosis: 2017; Residual disease: RX; Days to last known disease status: 606 days (1.7 years); Days to last follow up: 606 days (1.7 years).
   Pathology details: Greatest tumor dimension: 5 cm (a second GDC size field records 2 cm).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 606.

Other clinical attributes
- Weight: 56 kg; Height: 166 cm; BMI: 20.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01369-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -27 days; Initial weight: 329 mg; Time between excision and freezing: 22 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01369-21: Section location: Temporal Lobe; Percent tumor nuclei: 90; Percent necrosis: 5.
- Sample C3N-01369-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -27 days; Method of sample procurement: Blood Draw.
